Somatic mutation profile of tumor specimen TCGA-OR-A5J1-01A (aliquot TCGA-OR-A5J1-01A-11D-A29I-10) from TCGA case TCGA-OR-A5J1, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 58.9 years (21,496 days).
Specimen TCGA-OR-A5J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd2a2ba2-670a-44a5-a413-3d7644407531.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J1-10A (Blood Derived Normal), aliquot TCGA-OR-A5J1-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5339fe97-39cf-4f57-bc19-f34ffdef58d2

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 17, Silent 11, Frame Shift Del 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEX5 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV61328576; called by muse, mutect2, varscan2
- H3C2 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.545); catalogued as rs1270004025, COSV52517864, COSV52519480; called by muse, mutect2, varscan2
- KLHDC4 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775869495, COSV54512459; called by muse, mutect2, varscan2
- KLHL3 | c.1286C>T p.T429M | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59051118; called by muse, mutect2, varscan2
- LAMA3 | c.5162G>A p.G1721D (on ENST00000313654 / NM_198129.4; = p.G112D on NM_000227.6) | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CD951762; called by muse, mutect2, varscan2
- OPN4 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as rs1564621019; called by muse, mutect2
- RBL1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs1021741402, COSV60331601; called by muse, mutect2
- SALL2 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764828751, COSV100444630; called by muse, mutect2, varscan2
- TACR3 | c.94del p.A32Rfs*85 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as COSV59206434; called by mutect2, pindel, varscan2
- TTN | c.36370A>G p.K12124E (on ENST00000591111; = p.K4700E on NM_003319.4) | Missense Mutation (SNP) | VAF 42/95 reads (44%) | PolyPhen possibly damaging (0.84); catalogued as rs1376605407; called by muse, mutect2, varscan2
- ANK2 | c.7487C>G p.T2496R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- DDO | c.746A>C p.E249A (on ENST00000368924 / NM_001368172.1; = p.E190A on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FRAS1 | c.7953G>A p.M2651I | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- KLRB1 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOL11 | c.1528A>C p.S510R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RBM28 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCFD2 | c.726A>C p.L242F | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM266 | c.657del p.Y219* | Frame Shift Del (DEL) | VAF 64/190 reads (34%) | called by mutect2, pindel, varscan2
- TMEM40 | c.424+1G>C p.X142_splice | Splice Site (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- TRAM1L1 | c.31_40del p.P11Sfs*127 | Frame Shift Del (DEL) | VAF 47/112 reads (42%) | called by mutect2, pindel, varscan2
- WDR7 | c.325T>C p.C109R | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ANKRD24 | c.1009C>T p.L337= | Silent (SNP) | VAF 157/364 reads (43%) | catalogued as rs753906200; called by muse, mutect2, varscan2
- DISP3 | c.477G>A p.L159= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- DNMT3A | c.363A>T p.A121= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- GABRA1 | c.330C>T p.V110= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- NTMT1 | c.105C>T p.G35= | Silent (SNP) | VAF 66/157 reads (42%) | called by muse, mutect2, varscan2
- PHC2 | c.1542G>A p.P514= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as rs557095087, COSV57103486; called by muse, mutect2, varscan2
- SCARF1 | c.1083G>A p.G361= | Silent (SNP) | VAF 56/170 reads (33%) | called by muse, mutect2, varscan2
- SNAPC4 | c.3732G>A p.Q1244= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- THOP1 | c.51G>A p.P17= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs748415848; called by muse, mutect2, varscan2
- TRAK1 | c.2739C>T p.G913= | Silent (SNP) | VAF 68/152 reads (45%) | called by muse, mutect2, varscan2
- VPS13D | c.552T>G p.A184= | Silent (SNP) | VAF 48/118 reads (41%) | called by muse, mutect2, varscan2
